Somatic mutation profile of tumor specimen TCGA-AX-A1CK-01A (aliquot TCGA-AX-A1CK-01A-11D-A135-09) from TCGA case TCGA-AX-A1CK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.0 years (21,200 days).
Specimen TCGA-AX-A1CK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99a32864-93f7-4225-989b-50d19229b216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CK-11A (Solid Tissue Normal), aliquot TCGA-AX-A1CK-11A-11D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e7363d8-c9aa-472c-9239-b6dbc65ecd0f

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Frame Shift Del 5, Nonsense Mutation 4, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- PTEN | c.1116_1119del p.E373Lfs*42 | Frame Shift Del (DEL) | VAF 48/118 reads (41%) | catalogued as rs1554826049; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- ATP2B2 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776369165; called by muse, mutect2, varscan2
- BCOR | c.3487C>T p.R1163* | Nonsense Mutation (SNP) | VAF 46/98 reads (47%) | catalogued as COSV60713352; called by muse, mutect2, varscan2
- BPIFB3 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as rs752156774, COSV64957094; called by muse, varscan2
- CCDC66 | c.1868C>T p.T623I (on ENST00000394672 / NM_001353147.1; = p.T589I on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs747006960, COSV100413703; called by muse, mutect2, varscan2
- CDH9 | c.1671T>A p.S557R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV99141875; called by muse, mutect2, varscan2
- CNTN4 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761504879, COSV61877512; called by muse, mutect2, varscan2
- DIDO1 | c.6368G>A p.W2123* | Nonsense Mutation (SNP) | VAF 41/75 reads (55%) | catalogued as rs1340070718, COSV99824855; called by muse, mutect2, varscan2
- DMXL2 | c.3697_3699del p.L1233del | In Frame Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs754617255; called by pindel, varscan2
- DYSF | c.2397G>C p.Q799H | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV50269010, COSV99244520; called by muse, mutect2, varscan2
- EHF | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99140862; called by muse, mutect2, varscan2
- EN2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52082718; called by muse, mutect2, varscan2
- FCN1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs199881741; called by muse, mutect2, varscan2
- GPR6 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV51571247, COSV51573087; called by muse, mutect2, varscan2
- HIP1R | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as rs367922574; called by muse, mutect2, varscan2
- HS3ST4 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767787078, COSV58805742; called by muse, mutect2, varscan2
- IFNA21 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 135/278 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs573305591, COSV66518978; called by muse, mutect2, varscan2
- MAP1A | c.7507G>T p.A2503S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV100288116; called by muse, mutect2, varscan2
- MMRN2 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100922501; called by muse, mutect2, varscan2
- PGK1 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100965291; called by muse, mutect2, varscan2
- PRX | c.3014G>A p.G1005D | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV99397485; called by muse, mutect2, varscan2
- RYR2 | c.4990G>A p.V1664I | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs749434532, COSV63698965, COSV63705585; called by muse, mutect2, varscan2
- TAF1 | c.2467C>T p.R823W (on ENST00000373790 / NM_138923.4; = p.R844W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111149; called by muse, mutect2, varscan2
- TANC1 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1417405710, COSV99713126; called by muse, varscan2
- TCEAL2 | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100216225; called by muse, mutect2, varscan2
- TFAP2D | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.939); catalogued as COSV50436730, COSV50437640; called by muse, mutect2, varscan2
- TFDP1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750890106, COSV64739777, COSV64740643; called by muse, mutect2, varscan2
- TNFSF18 | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 57/243 reads (23%) | catalogued as COSV99513821; called by muse, mutect2, varscan2
- TRMT2B | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100105185; called by muse, mutect2, varscan2
- USP7 | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100783991; called by muse, mutect2, varscan2
- UTRN | c.8782G>A p.V2928I | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs375664557; called by muse, mutect2, varscan2
- WDR11 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99071458, COSV99676267; called by muse, mutect2, varscan2
- ZMYM2 | c.2545G>T p.A849S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV101243540; called by muse, mutect2, varscan2
- ZMYM2 | c.2546C>A p.A849E | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101243541, COSV67035080; called by muse, mutect2, varscan2
- ZNF587 | c.1438A>C p.T480P | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100299317; called by muse, mutect2, varscan2
- ZNF91 | c.2337T>G p.F779L | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100322219; called by muse, mutect2, varscan2
- AKAP13 | c.5907_5911del p.K1969Nfs*31 (on ENST00000394518 / NM_007200.5; = p.K1973Nfs*31 on NM_006738.6) | Frame Shift Del (DEL) | VAF 38/96 reads (40%) | called by mutect2, varscan2
- DYRK1A | c.256_266del p.R86Nfs*10 | Frame Shift Del (DEL) | VAF 36/71 reads (51%) | called by mutect2, pindel, varscan2
- EP300 | c.1803del p.D602Tfs*7 | Frame Shift Del (DEL) | VAF 97/226 reads (43%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NOLC1 | c.1454_1455del p.T485Ifs*2 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- ANKMY1 | c.286C>T p.L96= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56040766; called by muse, mutect2, varscan2
- CFAP74 | c.531G>A p.E177= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- DPEP1 | c.1218C>T p.L406= | Silent (SNP) | VAF 66/101 reads (65%) | catalogued as COSV99878307; called by muse, mutect2, varscan2
- DRP2 | c.2463C>T p.D821= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs1047599457, COSV67870963; called by muse, mutect2, varscan2
- FARSB | c.768G>A p.T256= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as rs766300429, COSV99918178; called by muse, mutect2, varscan2
- GALNT13 | c.732T>G p.T244= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as COSV101222246; called by muse, mutect2, varscan2
- LAMA1 | c.7902G>A p.T2634= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs756727988, COSV101055122; called by muse, mutect2, varscan2
- OR3A2 | c.402C>T p.A134= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs1187551239, COSV101375034; called by muse, mutect2, varscan2
- PDGFD | c.118C>A p.R40= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs1285007629, COSV100157898; called by muse, mutect2, varscan2
- PDGFRB | c.2511C>A p.G837= | Silent (SNP) | VAF 45/84 reads (54%) | catalogued as COSV99940189; called by muse, mutect2, varscan2
- S100A3 | c.282C>T p.P94= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV100573021; called by muse, mutect2, varscan2
- SPHK2 | c.1017C>T p.F339= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs1410978846, COSV55339273; called by muse, mutect2, varscan2
- LINC01098 | n.751dup | RNA (INS) | VAF 46/119 reads (39%) | catalogued as rs765631673; called by mutect2, pindel, varscan2
- XIST | n.9409C>T | RNA (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
